Somatic mutation profile of tumor specimen TCGA-HT-8012-01A (aliquot TCGA-HT-8012-01A-11D-2395-08) from TCGA case TCGA-HT-8012, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Oligodendroglioma, NOS; Tissue or organ of origin: Cerebrum; Tumor grade: G2; Age at diagnosis: 30.9 years (11,295 days).
Specimen TCGA-HT-8012-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1e965499-bf1a-4d46-aca5-55a42cb700c2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-HT-8012-10A (Blood Derived Normal), aliquot TCGA-HT-8012-10A-01D-2396-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ad35784d-7fdb-4767-aaa6-6ef4d0b43eee

The open-access MAF lists 25 somatic variants for this specimen: 16 protein-altering or splice-affecting, 9 silent.
By variant classification: Missense Mutation 10, Silent 9, Frame Shift Del 4, In Frame Del 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 30/67 reads (45%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- NOTCH1 | c.1070_1072del p.F357del | In Frame Del (DEL) | VAF 6/38 reads (16%) | hotspot (GDC flag); called by mutect2, varscan2
- B4GALNT3 | c.753G>C p.Q251H | Missense Mutation (SNP) | VAF 22/51 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56752279; called by muse, mutect2, varscan2
- CLUH | c.3347G>A p.G1116E (on ENST00000435359; = p.G1155E on NM_015229.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.714); catalogued as rs1409156052, COSV70928108, COSV70928462; called by muse, mutect2, varscan2
- DLG5 | c.1133C>T p.A378V | Missense Mutation (SNP) | VAF 56/123 reads (46%) | SIFT tolerated (0.96); PolyPhen benign (0.033); catalogued as rs1391008248, COSV64947957; called by muse, mutect2, varscan2
- IL1RL1 | c.857T>A p.V286D | Missense Mutation (SNP) | VAF 46/182 reads (25%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.446); catalogued as COSV52115616; called by muse, mutect2, varscan2
- MSMO1 | c.848A>G p.E283G | Missense Mutation (SNP) | VAF 24/52 reads (46%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as COSV54970207; called by mutect2, varscan2
- OMA1 | c.764A>G p.E255G | Missense Mutation (SNP) | VAF 19/23 reads (83%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.569); catalogued as rs777645857, COSV62255416; called by muse, mutect2
- POLR3K | c.287A>G p.K96R | Missense Mutation (SNP) | VAF 46/111 reads (41%) | SIFT tolerated (0.33); PolyPhen benign (0.309); catalogued as rs1412059858, COSV53452794; called by muse, mutect2, varscan2
- RNF17 | c.2231G>A p.R744Q | Missense Mutation (SNP) | VAF 20/106 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV55040350; called by muse, mutect2, varscan2
- TAF1 | c.5129G>T p.S1710I (on ENST00000373790 / NM_138923.4; = p.S1731I on NM_004606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/150 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.962); catalogued as COSV52113094; called by muse, mutect2
- CIC | c.1110_1113del p.S370Rfs*6 | Frame Shift Del (DEL) | VAF 26/79 reads (33%) | called by mutect2, pindel, varscan2
- CIC | c.3112_3113del p.V1038Sfs*112 | Frame Shift Del (DEL) | VAF 8/54 reads (15%) | called by mutect2, pindel
- GIGYF2 | c.2892_2895del p.Q964Hfs*7 | Frame Shift Del (DEL) | VAF 4/16 reads (25%) | called by mutect2, varscan2
- MYH7B | c.3043_3045del p.E1015del | In Frame Del (DEL) | VAF 17/45 reads (38%) | called by mutect2, pindel, varscan2
- PMPCB | c.803_804del p.K268Rfs*15 | Frame Shift Del (DEL) | VAF 10/50 reads (20%) | called by mutect2, pindel, varscan2
- ARR3 | c.936G>T p.L312= | Silent (SNP) | VAF 55/143 reads (38%) | catalogued as COSV52103935; called by muse, mutect2, varscan2
- B4GALNT3 | c.2163C>T p.R721= | Silent (SNP) | VAF 38/96 reads (40%) | catalogued as rs150429681; called by muse, mutect2, varscan2
- BEGAIN | c.798G>A p.A266= | Silent (SNP) | VAF 12/43 reads (28%) | catalogued as rs778052050, COSV62068721; called by muse, mutect2, varscan2
- CTAG2 | c.213G>A p.A71= | Silent (SNP) | VAF 19/79 reads (24%) | catalogued as rs140132753, COSV55994770; called by muse, mutect2, varscan2
- FASN | c.336C>T p.S112= | Silent (SNP) | VAF 40/106 reads (38%) | catalogued as rs775026834, COSV60754616; called by muse, mutect2, varscan2
- IGHA2 | c.891C>A p.T297= | Silent (SNP) | VAF 4/44 reads (9%) | called by muse, mutect2
- NTRK1 | c.792G>A p.T264= | Silent (SNP) | VAF 9/126 reads (7%) | catalogued as rs201110800, COSV62323002; called by muse, mutect2
- PTK2B | c.2562G>A p.G854= | Silent (SNP) | VAF 42/105 reads (40%) | catalogued as COSV57756291; called by muse, mutect2, varscan2
- TFCP2L1 | c.438C>T p.S146= | Silent (SNP) | VAF 4/42 reads (10%) | catalogued as rs1231763643, COSV55291056; called by muse, mutect2
